Gene-level copy-number profile of tumor specimen C3N-00249-03 from CPTAC case C3N-00249, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.5 years (26,108 days).
Specimen C3N-00249-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eca4bd05-e12c-4747-b4b5-a9728a794bd4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00249-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/42135269-78aa-46bc-8776-93b1b87f4ce4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 207; copy number 1: 10; copy number 2: 19,808; copy number 3: 314; copy number 4: 33,377; copy number 5: 2,529; copy number 6: 2,528; copy number 7: 1; copy number 8: 45; copy number 9: 1; copy number 10: 54; copy number 13: 2; copy number 25: 3.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr13:110,916,004–110,917,827, 1 gene: AL442128.2.
- chr17:68,267,026–68,291,267, 1 gene (within-gene range 0–2): SLC16A6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:37,383,178–39,039,594, 46 genes, copy number 10: LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5, AL138752.2, RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3, DCAF10, AL138752.1, PAICSP1, SLC25A51, TMX2P1, SHB, RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P.
- chr9:41,573,156–41,648,035, 5 genes, copy number 13–25: AL591926.3, SNORA70, AL591926.7, AL591926.6, AL591926.5.
- chr16:90,173,217–90,222,851, 1 gene, copy number 9 (within-gene range 6–9): LINC02193.
- chr20:11,800,463–12,381,255, 8 genes, copy number 10: LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
